Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VJ-01A (Primary Tumor).

[page 1 of 3]
Result History

Result Date and Time

Status

Final result

Priority

Routine

Report Assistance Message

ICD-O-3
Carcinoma, Squamous cell NA
8670/3
Site: Cervix NOS
053.9
JAJ 4/4/13

Entry Date

Component Results

Surgical Pathology:

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

Pertinent Clinical Information

Cervical mass.

Pertinent Physical/Laboratory Findings: Cervical mass.

Gross Description

Specimen Material: Cervical biopsy.

The case is received in one part labeled with the patient's name
medical record number and given accession number.
and it is accompanied by a requisition form labeled with the same name and
accession number.

Received in formalin labeled with the patient's name and identification only
is a 0.7 x 0.5 x 0.3 cm tan-white tissue, which is filtered and submitted
in toto.

[page 2 of 3]
Pathology Assistant

Microscopic Description
Performed.

These findings were discussed with

The staff pathologist listed below has reviewed this case.

Staff Patnologist

Result History

Result Date and Time

Status

In process

Priority

Routine

Report Assistance Message

Results Routing Details for Order:

Result Collection

Outcome:

Routed using only CC list

Routing Scheme Used:

Routing Scheme Line:

Default

Resulting User:

Routing Instant:

Comments:

Routing Scheme configured to have no recipients

Current Status:

Routing Complete

Status History:

Result contact created

Routing started

Routing Complete

Result Collection

Outcome:

Result not sent

Resulting User:

Routing Instant:

Comments:

An message was not sent because no results were filed

Current Status:

Routing Complete

Status History:

Result contact created

Routing Complete

Order Transmittal Details for Order:

There is no tracking information for this order. Either the order has not gone through order transmittal or the tracking data has been purged from the system due to age.

Performance Data For

Print Group Name

ID

Server Time (sec)

Global Refs

Code Lines

Source: NCI Genomic Data Commons file 6601faab-0d53-4bc3-915a-8b4a5454ab5e (TCGA-JW-A5VJ.F62BE627-89E6-49C1-88BD-5FAC87777BDB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).